Gene-level copy-number profile of tumor specimen TCGA-AX-A3G4-01A from TCGA case TCGA-AX-A3G4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.5 years (22,099 days).
Specimen TCGA-AX-A3G4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.597029d3-33a7-4131-ab5a-3b25cf3c1e62.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3G4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6da37454-7196-4820-b91c-2dd13094d071

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 87; copy number 2: 14,994; copy number 3: 6,184; copy number 4: 16,775; copy number 5: 12,672; copy number 6: 5,080; copy number 7: 1,715; copy number 8: 910; copy number 9: 772; copy number 10: 53; copy number 11: 414; copy number 12: 48; copy number 13: 21; copy number 14: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3G4-01A-11D-A20R-01): tumor purity 0.61, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:67,379,378–67,806,600, 1 gene (within-gene range 0–2): AC112206.2.
- chr5:67,608,654–69,007,185, 20 genes (within-gene range 0–2): AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2, AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2, AC010280.1, AC010280.3, AC093523.1, VWA8P1, U8.
- chr20:12,865,202–13,638,932, 12 genes: LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,296 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,380,792–42,892,430, 25 genes, copy number 9 (within-gene range 5–9): RIMKLA, AL513331.1, ZMYND12, PPCS, CCDC30, RPS3AP11, TMSB4XP1, RNU6-536P, AL445669.1, PPIH, AC098484.4, AC098484.2, YBX1, CLDN19, P3H1, C1orf50, AC098484.3, AC098484.1, TMEM269, SVBP, ERMAP, AL512353.1, ZNF691, AL512353.2, MKRN8P.
- chr1:85,276,388–85,708,433, 10 genes, copy number 9 (within-gene range 5–9): AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6.
- chr1:116,754,430–117,243,508, 13 genes, copy number 11 (within-gene range 5–11): CD2, FTH1P22, AL157904.1, PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP.
- chr1:151,036,321–152,042,774, 63 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:204,346,776–204,616,565, 10 genes, copy number 9: AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3.
- chr1:204,626,775–204,629,712, 1 gene, copy number 9: AL512306.2.
- chr2:101,962,056–102,250,255, 7 genes, copy number 10: LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP.
- chr2:151,832,771–152,284,460, 6 genes, copy number 10 (within-gene range 4–10): CACNB4, AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA.
- chr2:152,389,937–152,390,630, 1 gene, copy number 10: NUDCP1.
- chr2:158,795,317–158,935,985, 6 genes, copy number 12: DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P.
- chr2:159,003,975–159,027,142, 2 genes, copy number 12: BTF3L4P2, RNU6-580P.
- chr2:172,137,345–172,506,459, 7 genes, copy number 12 (within-gene range 7–12): AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1.
- chr2:188,974,373–209,387,322, 378 genes, copy number 9–14 (broad region; genes not listed).
- chr3:71,943,592–72,324,027, 11 genes, copy number 9 (within-gene range 6–9): LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1.
- chr3:169,613,510–170,454,733, 32 genes, copy number 12: AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 12: MIR6828.
- chr3:196,739,857–196,832,647, 1 gene, copy number 14 (within-gene range 8–14): PAK2.
- chr3:196,784,980–197,299,330, 12 genes, copy number 14 (within-gene range 8–14): RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1.
- chr5:8,839,700–9,550,609, 11 genes, copy number 9 (within-gene range 7–9): LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123.
- chr5:10,337,277–10,777,062, 23 genes, copy number 9: Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:13,637,919–14,532,128, 5 genes, copy number 9 (within-gene range 7–9): AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:35,678,484–36,876,700, 25 genes, copy number 10 (within-gene range 4–10): AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT.
- chr5:36,885,206–36,886,497, 1 gene, copy number 10: KRT18P31.
- chr7:1,232,872–1,747,954, 17 genes, copy number 9: UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr9:34,179,005–34,546,996, 18 genes, copy number 14: UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2.
- chr12:47,661,249–48,040,761, 24 genes, copy number 11 (within-gene range 6–11): RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6.
- chr12:95,076,749–95,551,476, 15 genes, copy number 9 (within-gene range 4–9): FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44.
- chr17:17,494,437–18,268,828, 34 genes, copy number 11–13: RASD1, AC020558.6, PEMT, AC020558.2, RNU6-468P, AC020558.1, AC020558.5, SMCR2, AC020558.3, AC020558.4, RAI1, RAI1-AS1, SMCR5, AC122129.2, SREBF1, MIR6777, MIR33B, TOM1L2, AC122129.1, DRC3, ATPAF2, BRI3P3, AC087163.1, AC087163.2, GID4, DRG2, AC087164.2, MYO15A, AC087164.1, ALKBH5, LLGL1, FLII, MIEF2, AC127537.1.
- chr17:67,070,444–82,490,537, 525 genes, copy number 9–13 (broad region; genes not listed).
- chr18:47,390–500,722, 12 genes, copy number 9 (within-gene range 4–9): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2.

Autosomal genes at a single copy (total copy number 1): 87. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
